MMRF case MMRF_2106 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/eef55ab4-7778-4012-a217-4bb1def5a973

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Dead; Days to death: 344 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.6 years (19,958 days); ISS stage: I; Days to last known disease status: 344 days; Days to last follow up: 344 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 225 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 271 days; Days to treatment end: 272 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 271 days; Days to treatment end: 337 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 272 days; Days to treatment end: 277 days.
   Treatment given: Therapeutic agents: Bortezomib + Doxorubicin; Regimen or line of therapy: Second line of therapy; Days to treatment start: 276 days; Days to treatment end: 276 days.
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 337 days; Days to treatment end: 337 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 344.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 1): M Protein 4.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 30.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.659 mg/dL; Immunoglobulin G 50.7 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.88 µg/mL; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 10.2 g/dL; Glucose 4.51 mmol/L; C-Reactive Protein 0.4 mg/dL.
- Day 79 (ECOG 1): Hemoglobin 6.82 mmol/L; Leukocytes 2.4 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.03 mmol/L; Glucose 5.01 mmol/L.
- Day 159 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 9.12 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 5.56 mmol/L.
- Day 250 (ECOG 1): M Protein 1.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.679 mg/dL; Immunoglobulin G 24.2 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 5.05 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.03 mmol/L; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -10: Weight: 56 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_2106_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_2106_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
